Somatic mutation profile of tumor specimen BA2193D (aliquot aq-BA2193D) from BEATAML1.0 case 2408, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, CBF-beta/MYH11; Tissue or organ of origin: Bone marrow; Age at diagnosis: 33.1 years (12,099 days).
Specimen BA2193D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c729dc4-5e76-4be1-a7fb-a56225c3f303.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2043D (Solid Tissue Normal), aliquot aq-BA2043D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99851ef8-7f30-4c37-bbe1-0a20181cc2b3

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PANK3 | c.901A>T p.I301F | Missense Mutation (SNP) | VAF 24/202 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs77612793; called by muse, mutect2
- ZNF462 | c.5118C>A p.N1706K | Missense Mutation (SNP) | VAF 3/53 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- FZD5 | c.54G>T p.A18= | Silent (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- KIAA0232 | c.-2T>G | 5'UTR (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
